Gene-level copy-number profile of tumor specimen ALCH-B39Q-TTP1-A from ALCHEMIST case ALCH-B39Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 79.2 years (28,917 days).
Specimen ALCH-B39Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8b20362-fb11-473e-a0bc-c8e348e064ae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B39Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/23f6bef4-1624-48ff-84f3-ecdb28674936

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 18,619; copy number 2: 35,628; copy number 3: 3,206; copy number 4: 261; copy number 5: 320; copy number 6: 3; copy number 7: 48; copy number 9: 200; copy number 10: 3; copy number 11: 41; copy number 12: 19; copy number 14: 8; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,635,091, 8 genes: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–2): RNU6-904P, RPS16P3.
- chr3:52,777,595–52,835,729, 6 genes (within-gene range 0–1): ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr17:16,438,767–16,492,193, 6 genes: SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr19:956,485–958,149, 1 gene (within-gene range 0–2): AC005391.1.
- chr19:1,241,746–1,244,825, 1 gene: ATP5F1D.
- chr19:1,815,249–1,816,238, 2 genes (within-gene range 0–4): AC012615.2, MIR1909.
- chr19:29,811,991–29,824,312, 1 gene: CCNE1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 643 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:153,384,934–153,980,186, 2 genes, copy number 5 (within-gene range 3–5): LINC02006, LINC02877.
- chr3:153,881,526–155,183,704, 17 genes, copy number 5 (within-gene range 3–5): AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2, AC073359.1, MME.
- chr3:166,861,944–172,604,006, 99 genes, copy number 5–14 (broad region; genes not listed).
- chr3:175,938,929–187,207,629, 241 genes, copy number 5–11 (broad region; genes not listed).
- chr7:91,264,433–94,077,157, 53 genes, copy number 5: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr7:99,238,829–99,325,826, 2 genes, copy number 10: MYH16, AC004834.1.
- chr7:107,044,705–110,534,757, 44 genes, copy number 5: PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2.
- chr9:136,658,856–136,672,678, 2 genes, copy number 7–10 (within-gene range 2–10): EGFL7, MIR126.
- chr11:1,983,237–2,001,470, 6 genes, copy number 12–21 (within-gene range 2–21): MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr19:1,275,530–1,279,244, 1 gene, copy number 11: FAM174C.
- chr22:18,340,145–21,396,590, 176 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
